Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7Z3, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7Z3-01A (Primary Tumor).

Patient: [REDACTED]

Surgical Pathology: Final [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

year old black female.

GROSS EXAMINATION:

A. "Frozen section, right parietal tumor". The specimen consist of a irregularly shaped gelatinous mass which measures 3.2 x 2.5 x 2.0 cm. Two portion of this lesion are used frozen section. The remnant of frozen section number 1 is submitted in [REDACTED] and that of frozen section number 2 in [REDACTED]. Additional representative portions of the lesion are submitted in [REDACTED].

B. "Right parietal tumor". The specimen consists of a piece of gray-white tissue which measures 0.3 x 0.3 x 0.4 cm. The entire specimen is submitted in Block B1.

INTRA OPERATIVE CONSULTATION:

AF1 and AF2: Well differentiated glioma.

Per TSS, grade II.

DIAGNOSIS:

A. "FROZEN SECTION, RIGHT PARIETAL TUMOR":

BCR

ASTROCYTOMA. SEE COMMENT.

B. "RIGHT PARIETAL TUMOR":

ASTROCYTOMA. SEE COMMENT

(Electronic Signature)

Date Signed: [REDACTED]

COMMENT:

The Ki67 index is in some areas less than 1% whereas focally it is approximately 2%.

ICD-O 3

Astrocytoma, grade II 9400/3
Site: ^{CHU} Brain, supratentorial C71.0
path Brain NOS C71.9

JCO 5/5/14

NIHAA Discrepancy		

Source: NCI Genomic Data Commons file a1450bec-9372-4afd-aea0-aed1846fce48 (TCGA-E1-A7Z3.A522B02B-1349-44FD-9AEA-3FDA3BBFE4D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).